Somatic mutation profile of tumor specimen TCGA-CW-6087-01A (aliquot TCGA-CW-6087-01A-11D-1669-08) from TCGA case TCGA-CW-6087, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 61.4 years (22,438 days).
Specimen TCGA-CW-6087-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d624b2a1-9e5e-405e-b444-7f352a1f9984.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CW-6087-11A (Solid Tissue Normal), aliquot TCGA-CW-6087-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f98fd91c-b0d1-4593-a31c-2679d9dfa3b7

The open-access MAF lists 66 somatic variants for this specimen: 46 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 17, Nonsense Mutation 5, Frame Shift Del 2, Intron 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3209T>A p.V1070E | Missense Mutation (SNP) | VAF 64/223 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59257121, COSV59259138, COSV59261515; called by muse, mutect2, varscan2
- ACOX2 | c.2018T>C p.L673P | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57147754; called by muse, mutect2, varscan2
- ADCY8 | c.2183C>A p.A728E | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV53897284; called by muse, varscan2
- AGTPBP1 | c.3188A>G p.H1063R (on ENST00000357081 / NM_001330701.2; = p.H1023R on NM_015239.2) | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as COSV61268808; called by muse, mutect2, varscan2
- ANKRD30A | c.3425A>T p.K1142M (on ENST00000611781; = p.K1086M on NM_052997.2) | Missense Mutation (SNP) | VAF 25/297 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64604431; called by muse, mutect2
- ATG2B | c.4193G>C p.G1398A | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.049); catalogued as COSV55889451; called by muse, mutect2
- BEST3 | c.1689T>G p.S563R | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV58298919; called by muse, mutect2
- CACNA1E | c.4790T>C p.L1597P | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV62383151; called by muse, mutect2
- CASP8AP2 | c.1685T>A p.L562* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | catalogued as COSV52745350; called by muse, mutect2
- CPT1A | c.345G>A p.W115* | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as COSV55753082; called by muse, mutect2, varscan2
- CRAT | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 49/459 reads (11%) | catalogued as rs567401147, COSV58876069; called by muse, mutect2, varscan2
- DRC1 | c.809A>T p.E270V | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56529198; called by muse, mutect2
- EXTL1 | c.857T>A p.F286Y | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65337089, COSV65337929; called by muse, mutect2, varscan2
- FOXJ3 | c.414A>T p.K138N | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV62360049; called by muse, mutect2
- FTMT | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1259916791, COSV58419700; called by muse, mutect2, varscan2
- GAL3ST1 | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58891930; called by muse, mutect2, varscan2
- GALNT11 | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57424614; called by muse, mutect2, varscan2
- HAUS7 | c.1039A>G p.I347V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV57847889; called by muse, mutect2, varscan2
- HMGCS1 | c.853A>T p.N285Y | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV57289388; called by muse, mutect2, varscan2
- KCNJ15 | c.309T>G p.N103K | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as COSV60810252; called by muse, mutect2, varscan2
- MEP1A | c.1164G>A p.W388* | Nonsense Mutation (SNP) | VAF 10/165 reads (6%) | catalogued as COSV57918053, COSV57921239; called by muse, mutect2
- MESP1 | c.728T>A p.L243H | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); catalogued as COSV55588088; called by muse, mutect2, varscan2
- MGAT5B | c.1732G>A p.V578M (on ENST00000569840 / NM_001199172.2; = p.V576M on NM_144677.3) | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56925503; called by muse, mutect2, varscan2
- MSR1 | c.178G>C p.V60L | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as COSV50506984, COSV50534859; called by muse, mutect2, varscan2
- NARS2 | c.1127T>G p.F376C | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55249674; called by muse, mutect2, varscan2
- PCDHA6 | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65342026; called by muse, mutect2
- PCDHB9 | c.1412G>A p.G471D | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53375544; called by muse, mutect2, varscan2
- PHYHIP | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV58688043; called by muse, mutect2
- PLTP | c.298C>A p.R100S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.96); PolyPhen benign (0.058); catalogued as rs751016959, COSV62463820, COSV62465543; called by muse, mutect2, varscan2
- POLL | c.176A>T p.E59V | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV54573658; called by muse, mutect2, varscan2
- PREX1 | c.1663C>A p.Q555K | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV64248065; called by muse, mutect2, varscan2
- PRKACG | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs138606760; called by muse, mutect2, varscan2
- RBP3 | c.2185C>A p.L729I | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1372129460; called by muse, mutect2
- RGR | c.96C>A p.S32R | Missense Mutation (SNP) | VAF 11/311 reads (4%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.648); catalogued as COSV63893398; called by muse, mutect2
- SAV1 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 13/115 reads (11%) | catalogued as COSV61204353; called by muse, mutect2, varscan2
- SGK2 | c.616G>C p.A206P | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58312152; called by muse, mutect2, varscan2
- SGK3 | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.425); catalogued as COSV61893681; called by muse, mutect2, varscan2
- SIPA1L3 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV55909207; called by muse, mutect2, varscan2
- SORCS3 | c.2875A>T p.I959F | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV63793512; called by muse, mutect2
- SRA1 | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); catalogued as COSV51840874; called by muse, mutect2, varscan2
- TOB1 | c.425T>C p.I142T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV52149805; called by muse, mutect2, varscan2
- TSHZ1 | c.1132G>A p.E378K (on ENST00000580243 / NM_001308210.2; = p.E333K on NM_005786.6) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV59005800; called by muse, mutect2, varscan2
- UPF1 | c.491A>G p.K164R | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.073); catalogued as COSV53193903; called by muse, mutect2, varscan2
- VWA3B | c.1759C>G p.L587V | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV68241026, COSV68244223; called by muse, mutect2
- CFAP251 | c.2327_2328del p.R776Kfs*48 | Frame Shift Del (DEL) | VAF 14/146 reads (10%) | called by mutect2, pindel
- ELF3 | c.15del p.C5Wfs*38 | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | called by mutect2, pindel, varscan2
- AHSA1 | c.378T>C p.D126= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as COSV53631108; called by muse, mutect2, varscan2
- EIF4G3 | c.1107G>A p.T369= | Silent (SNP) | VAF 21/206 reads (10%) | catalogued as rs150884106, COSV51674495; called by muse, mutect2, varscan2
- ESRRA | c.594G>A p.V198= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs372946185; called by muse, mutect2
- IFNLR1 | c.978A>G p.E326= | Silent (SNP) | VAF 42/292 reads (14%) | catalogued as COSV59525258; called by muse, mutect2, varscan2
- PABPC1 | c.888T>C p.L296= | Silent (SNP) | VAF 43/280 reads (15%) | catalogued as COSV59398496; called by muse, mutect2, varscan2
- PATJ | c.2928T>A p.L976= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as COSV57156007; called by muse, mutect2
- PCDH19 | c.846C>T p.N282= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs750813033, COSV55257979; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCSK2 | c.1032C>T p.D344= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs1193757704, COSV52726778, COSV52734911; called by muse, mutect2, varscan2
- PLA2G2F | c.300G>A p.K100= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV64279776, COSV64279972; called by muse, mutect2
- POM121L12 | c.594C>T p.F198= | Silent (SNP) | VAF 15/147 reads (10%) | catalogued as rs1398358196, COSV68692268; called by muse, mutect2, varscan2
- SCN10A | c.2007C>A p.L669= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV71860340; called by muse, mutect2, varscan2
- SORCS3 | c.2874C>A p.L958= | Silent (SNP) | VAF 16/226 reads (7%) | catalogued as COSV63793499; called by muse, mutect2
- TNK2 | c.2514G>A p.P838= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs566117421, COSV57366035; called by muse, mutect2, varscan2
- UGT2B10 | c.1071C>T p.P357= | Silent (SNP) | VAF 12/125 reads (10%) | catalogued as rs202031177, COSV55318740; called by muse, mutect2, varscan2
- VCAN | c.5208T>A p.S1736= | Silent (SNP) | VAF 16/145 reads (11%) | catalogued as COSV54097463; called by muse, mutect2
- WDR7 | c.2499A>G p.V833= | Silent (SNP) | VAF 25/238 reads (11%) | catalogued as rs1362814431, COSV54348532; called by muse, mutect2, varscan2
- ZNF608 | c.843G>A p.L281= | Silent (SNP) | VAF 34/396 reads (9%) | catalogued as COSV60435472; called by muse, mutect2
- CACNA1G | c.4422+208G>A | Intron (SNP) | VAF 4/9 reads (44%) | catalogued as rs199892912; called by muse, mutect2
- SH2B2 | chr7:102281886 T>G | 5'Flank (SNP) | VAF 25/77 reads (32%) | catalogued as COSV52923706; called by muse, mutect2, varscan2
- TCF3 | c.1823-543G>T | Intron (SNP) | VAF 12/94 reads (13%) | catalogued as COSV53645833; called by muse, mutect2
